Somatic mutation profile of tumor specimen TCGA-EE-A29N-06A (aliquot TCGA-EE-A29N-06A-12D-A197-08) from TCGA case TCGA-EE-A29N, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 79.6 years (29,082 days).
Specimen TCGA-EE-A29N-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 533df9bc-171f-4680-9129-b3b787a86bce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A29N-10A (Blood Derived Normal), aliquot TCGA-EE-A29N-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1dd6248-4e2d-4e22-ad47-9d00b8acc406

The open-access MAF lists 748 somatic variants for this specimen: 482 protein-altering or splice-affecting, 248 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 426, Silent 248, Nonsense Mutation 35, Frame Shift Del 9, Splice Site 9, RNA 7, Intron 6, 5'Flank 4, Splice Region 2, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KCNQ5 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 9/56 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59663556; called by muse, mutect2, varscan2
- KRAS | c.351A>C p.K117N | Missense Mutation (SNP) | VAF 26/109 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- UCHL1 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 14/93 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52651371; called by muse, mutect2, varscan2
- AADACL2 | c.636C>G p.I212M | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV62930793, COSV62932362; called by muse, mutect2, varscan2
- ABCA13 | c.11822C>T p.S3941F | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71289381; called by muse, mutect2, varscan2
- ABCA5 | c.3474G>A p.M1158I | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV101201201; called by muse, mutect2, varscan2
- ABHD12B | c.850C>T p.P284S (on ENST00000337334 / NM_001206673.2; = p.P207S on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.18); catalogued as COSV53586403; called by mutect2, varscan2
- ACBD3 | c.395T>C p.V132A | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64730456; called by muse, mutect2
- ACE2 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs764661406, COSV53024833; called by muse, mutect2, varscan2
- ACP3 | c.642T>G p.Y214* | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | catalogued as COSV60486789; called by muse, mutect2, varscan2
- ACSM2B | c.1142G>A p.G381E | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100312940; called by muse, mutect2, varscan2
- ADAM22 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV55978966; called by muse, mutect2
- ADAMTS4 | c.1553C>T p.P518L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV63490411; called by muse, mutect2, varscan2
- ADAMTS6 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66860100; called by muse, mutect2, varscan2
- ADAMTS9 | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 95/532 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs746299995, COSV55782937; called by muse, mutect2, varscan2
- ADGRB3 | c.416C>A p.P139Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV65399876, COSV65421074; called by muse, mutect2, varscan2
- ADGRE3 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV53731219; called by muse, mutect2, varscan2
- ADGRV1 | c.7669C>T p.Q2557* | Nonsense Mutation (SNP) | VAF 25/175 reads (14%) | catalogued as COSV67986115; called by muse, mutect2, varscan2
- ADH1B | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV59296813; called by muse, mutect2, varscan2
- AGL | c.2150T>A p.F717Y | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV54053574; called by muse, mutect2, varscan2
- AGPAT3 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.54); catalogued as COSV52370963; called by muse, mutect2, varscan2
- AHCYL2 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV61487960; called by muse, mutect2, varscan2
- AHNAK2 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV60917795; called by muse, mutect2, varscan2
- AHR | c.2281C>T p.P761S | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.965); catalogued as rs778166955, COSV99619984; called by muse, mutect2, varscan2
- AHR | c.2282C>T p.P761L | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.913); catalogued as COSV99619986; called by muse, mutect2, varscan2
- AL136295.1 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.289); catalogued as COSV55780033; called by muse, mutect2, varscan2
- AL441992.2 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56914356; called by muse, mutect2, varscan2
- AL592490.1 | c.1196T>C p.L399P | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69425542, COSV69426626; called by muse, mutect2, varscan2
- ALOX15B | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1263964443, COSV66479365; called by muse, mutect2, varscan2
- ANK1 | c.3108G>A p.M1036I | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs770492413, COSV55878374; called by muse, mutect2, varscan2
- ANK3 | c.6050A>G p.Q2017R | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.073); catalogued as COSV55061831; called by muse, mutect2, varscan2
- ANK3 | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV99781074; called by muse, varscan2
- ANKRD29 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as rs565335697, COSV52426199; called by muse, mutect2, varscan2
- ANLN | c.2821C>T p.L941F | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56076956; called by muse, mutect2, varscan2
- ANO4 | c.2524G>A p.E842K (on ENST00000392977 / NM_001286615.2; = p.E807K on NM_178826.4) | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as COSV54598610; called by muse, varscan2
- AOC2 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.545); catalogued as rs777486921, COSV99513713; called by muse, mutect2, varscan2
- APOL3 | c.512G>A p.R171H (on ENST00000349314 / NM_145640.2; = p.R100H on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as rs577244594, COSV62579985; called by muse, mutect2, varscan2
- ARFGAP3 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV54312353; called by muse, mutect2, varscan2
- ARFGEF2 | c.4471C>T p.P1491S | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV64212828; called by muse, mutect2, varscan2
- ARFGEF3 | c.5233G>A p.E1745K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.057); catalogued as COSV52459802; called by muse, mutect2, varscan2
- ARHGAP18 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs772632806, COSV63764653; called by muse, mutect2, varscan2
- ARHGAP21 | c.4526C>G p.S1509* | Nonsense Mutation (SNP) | VAF 40/285 reads (14%) | catalogued as COSV57606727; called by muse, mutect2, varscan2
- ARHGAP33 | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV50126024; called by muse, mutect2, varscan2
- ARID2 | c.2392C>T p.Q798* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV57596107; called by muse, mutect2, varscan2
- ARID2 | c.3580C>T p.Q1194* | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | catalogued as COSV57601778; called by muse, mutect2, varscan2
- ARMC9 | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63021384; called by muse, varscan2
- ARPP21 | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV51792609; called by muse, mutect2, varscan2
- ASIC5 | c.506T>G p.F169C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV72232857; called by muse, mutect2, varscan2
- ASXL1 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs1431666756, COSV100040297; called by muse, mutect2, varscan2
- ASXL3 | c.4089G>A p.M1363I | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV52468345, COSV99326795; called by muse, mutect2, varscan2
- ATP13A1 | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1464783845, COSV52282532; called by mutect2, varscan2
- ATP13A5 | c.1271G>A p.G424E | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.077); catalogued as rs749400403, COSV60870336; called by muse, mutect2, varscan2
- ATP5PD | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs1224974508, COSV56902947; called by muse, mutect2, varscan2
- B9D1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as COSV52069553; called by muse, mutect2, varscan2
- BACE2 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs530813869, COSV57740272; called by muse, mutect2, varscan2
- BACH2 | c.1858G>A p.D620N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.311); catalogued as COSV57595175; called by muse, mutect2, varscan2
- BAZ2B | c.2242C>T p.P748S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58602556; called by muse, mutect2
- BCL11A | c.2374C>T p.R792* (on ENST00000335712 / NM_001365609.1; = p.R826* on NM_022893.4) | Nonsense Mutation (SNP) | VAF 130/627 reads (21%) | catalogued as rs771597942, COSV59627412, COSV59629046; called by muse, mutect2, varscan2
- BICRAL | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as rs147851446; called by muse, mutect2, varscan2
- BPIFB2 | c.670-1G>A p.X224_splice | Splice Site (SNP) | VAF 30/190 reads (16%) | catalogued as COSV50065904; called by muse, mutect2, varscan2
- BPTF | c.2686C>T p.H896Y | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV58838694; called by muse, mutect2, varscan2
- BTBD16 | c.1184A>C p.K395T | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV53263795; called by muse, mutect2
- BTN1A1 | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 63/296 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.625); catalogued as rs767129953, COSV55068055; called by muse, mutect2, varscan2
- C17orf67 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 107/613 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV67375195; called by muse, mutect2, varscan2
- C2CD2 | c.1433-1G>A p.X478_splice | Splice Site (SNP) | VAF 5/28 reads (18%) | catalogued as COSV61599711; called by muse, mutect2
- C2orf16 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.225); catalogued as COSV68646259; called by muse, mutect2, varscan2
- C3 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs760637447, COSV55571795; called by muse, mutect2, varscan2
- C7orf26 | c.325A>T p.S109C | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.494); catalogued as COSV60106619; called by muse, mutect2, varscan2
- CACNA1G | c.5324C>T p.P1775L | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV61720057, COSV61729672; called by muse, mutect2, varscan2
- CALU | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV99975799, COSV99975925; called by muse, mutect2, varscan2
- CARM1 | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53403786; called by muse, mutect2, varscan2
- CASR | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.434); catalogued as COSV56134542; called by muse, mutect2, varscan2
- CASS4 | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV100824799; called by muse, mutect2, varscan2
- CCDC186 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.747); catalogued as COSV100991037; called by muse, mutect2, varscan2
- CCDC186 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.044); catalogued as rs1226695954, COSV65159734; called by muse, mutect2, varscan2
- CCDC54 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as COSV53758828; called by muse, mutect2, varscan2
- CCDC73 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104406442, COSV58799804; called by muse, mutect2, varscan2
- CCNQ | c.325del p.E109Nfs*21 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as COSV52345779; called by mutect2, pindel, varscan2
- CDH15 | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.53); catalogued as rs1425661967, COSV57024947; called by muse, mutect2
- CDK18 | c.129G>A p.E43= | Splice Region (SNP) | VAF 10/53 reads (19%) | catalogued as rs753132082, COSV63727760; called by muse, mutect2, varscan2
- CELSR3 | c.4766C>T p.P1589L | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV50879375; called by muse, mutect2, varscan2
- CELSR3 | c.3080G>A p.R1027Q | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50879594; called by muse, mutect2, varscan2
- CER1 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as COSV66602903; called by muse, mutect2, varscan2
- CETN1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV59121478; called by muse, mutect2, varscan2
- CFAP46 | c.7298C>T p.P2433L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs757325575, COSV54153573; called by muse, mutect2, varscan2
- CFAP61 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV55632545; called by muse, mutect2, varscan2
- CFTR | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs144720913, CM067769, COSV50060609, COSV50129630; called by muse, mutect2, varscan2
- CGNL1 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1191229057, COSV55569416; called by muse, mutect2, varscan2
- CHD6 | c.1338G>A p.W446* | Nonsense Mutation (SNP) | VAF 23/153 reads (15%) | catalogued as COSV100498501; called by muse, mutect2, varscan2
- CHD6 | c.1337G>A p.W446* | Nonsense Mutation (SNP) | VAF 23/153 reads (15%) | catalogued as COSV100498503; called by muse, mutect2, varscan2
- CHIA | c.658G>A p.G220S (on ENST00000343320; = p.G112S on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.129); catalogued as COSV58475855; called by muse, mutect2, varscan2
- CHRND | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51319107, COSV51320713; called by muse, mutect2, varscan2
- CLEC4C | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1049599097, COSV63582734; called by muse, mutect2, varscan2
- CMYA5 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV71406434; called by muse, mutect2, varscan2
- CMYA5 | c.11229G>A p.M3743I | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as rs777169534, COSV71406437; called by muse, mutect2, varscan2
- CNBD1 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373039361; called by muse, mutect2, varscan2
- CNDP1 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62593191; called by muse, mutect2, varscan2
- CNGA1 | c.716A>G p.N239S | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs772619232, COSV62054665, COSV62055335; called by muse, mutect2, varscan2
- CNPY3 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | catalogued as COSV65709864; called by muse, mutect2, varscan2
- CNTN1 | c.2978C>T p.S993L | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as COSV61640730; called by muse, mutect2, varscan2
- CNTRL | c.571A>C p.K191Q | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV53048151; called by muse, mutect2, varscan2
- COL10A1 | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs138141648, COSV54573307; called by muse, mutect2, varscan2
- COL18A1 | c.2837C>T p.P946L (on ENST00000359759 / NM_130444.3; = p.P711L on NM_030582.4) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62702692; called by muse, mutect2
- COL4A4 | c.3032G>A p.G1011E | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61631582; called by muse, mutect2, varscan2
- COL4A5 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.999); catalogued as COSV60363263; called by muse, mutect2, varscan2
- CPNE6 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53744554; called by muse, mutect2, varscan2
- CRX | c.364G>C p.G122R | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV99704587; called by muse, mutect2, varscan2
- CRYBA1 | c.71C>A p.T24K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.91); PolyPhen benign (0.013); catalogued as COSV56600986; called by muse, varscan2
- CRYZL1 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51677959; called by muse, mutect2, varscan2
- CSMD1 | c.3622C>T p.L1208F (on ENST00000520002; = p.L1207F on NM_033225.6) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59334106; called by muse, mutect2, varscan2
- CSMD3 | c.7988G>A p.R2663Q (on ENST00000297405 / NM_001363185.1; = p.R2559Q on NM_052900.3) | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.763); catalogued as rs1457467270, COSV52202931; called by muse, mutect2, varscan2
- CTIF | c.1564C>T p.L522F | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as COSV56482643; called by muse, mutect2, varscan2
- CTSA | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV99510033; called by muse, mutect2, varscan2
- CTSS | c.383C>T p.T128I | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64566455; called by muse, mutect2, varscan2
- CXCR6 | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV99945939; called by muse, mutect2, varscan2
- CXCR6 | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.03); catalogued as COSV99945942; called by muse, mutect2, varscan2
- CYFIP2 | c.2000C>T p.S667F (on ENST00000616178 / NM_001291722.2; = p.S642F on NM_014376.4) | Missense Mutation (SNP) | VAF 61/441 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59040873; called by muse, mutect2, varscan2
- CYP4F11 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56127473, COSV99930597; called by muse, mutect2, varscan2
- CYRIA | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as COSV62865422, COSV62866349; called by muse, mutect2, varscan2
- DDX24 | c.1500G>C p.K500N | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV58212724; called by muse, mutect2, varscan2
- DHX29 | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.217); catalogued as COSV52416372; called by muse, mutect2, varscan2
- DLGAP1 | c.2348C>T p.A783V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV59809433; called by muse, mutect2, varscan2
- DLGAP2 | c.2387G>A p.G796D | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV70093254, COSV70099446; called by muse, varscan2
- DMBT1 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 62/415 reads (15%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.994); catalogued as rs368897345; called by muse, mutect2, varscan2
- DNAH1 | c.1362T>A p.F454L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV70229968; called by mutect2, varscan2
- DNAH10 | c.4401G>A p.W1467* (on ENST00000409039; = p.W1406* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV68995183; called by muse, mutect2
- DNAH3 | c.4727G>A p.R1576K | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.3); catalogued as rs12927146, COSV54527064; called by muse, mutect2, varscan2
- DNAH7 | c.5935G>A p.G1979R | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1230563836, COSV56768600; called by muse, mutect2, varscan2
- DNAH8 | c.12762G>A p.M4254I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.377); catalogued as COSV59452616; called by muse, mutect2, varscan2
- DOCK2 | c.3391G>A p.E1131K | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1360509769, COSV56947114, COSV56971412; called by muse, mutect2, varscan2
- DOK2 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99374836; called by muse, mutect2, varscan2
- DRD2 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs201424743, COSV60758851; called by muse, mutect2, varscan2
- DRD5 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV58578624; called by muse, mutect2, varscan2
- DRD5 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.021); catalogued as COSV58578632; called by muse, mutect2
- DSCAM | c.5062G>A p.D1688N | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as COSV68028392; called by muse, mutect2, varscan2
- DSP | c.4373G>A p.R1458Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as rs370063434, COSV65791413; ClinVar: uncertain significance; called by mutect2, varscan2
- DZIP3 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.26); catalogued as COSV64312400; called by muse, mutect2, varscan2
- ECD | c.1181C>G p.P394R | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV65900133; called by muse, mutect2, varscan2
- ECT2L | c.2449C>T p.L817F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57811428; called by muse, mutect2, varscan2
- EIF2AK1 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV52239115; called by muse, mutect2, varscan2
- EIF4E1B | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0.024); catalogued as COSV53780612; called by muse, mutect2, varscan2
- ELFN2 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.92); catalogued as rs200557041, COSV68743789; called by muse, mutect2
- ELOA2 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs1455365305, COSV55298376; called by muse, mutect2, varscan2
- EPHA6 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 67/317 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750297483, COSV67556787; called by muse, varscan2
- EPHA6 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV67559487; called by muse, mutect2, varscan2
- ERBB2 | c.3562G>A p.G1188R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV99508524; called by mutect2, varscan2
- ERBB2 | c.3563G>A p.G1188E | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.392); catalogued as COSV99508528; called by muse, mutect2, varscan2
- ESRP1 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 82/542 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as COSV64407953; called by muse, mutect2, varscan2
- EVPL | c.4449G>A p.W1483* | Nonsense Mutation (SNP) | VAF 31/161 reads (19%) | catalogued as COSV56912156; called by muse, mutect2, varscan2
- EXOC7 | c.1462G>A p.D488N (on ENST00000335146 / NM_001145297.4; = p.D406N on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.37); catalogued as COSV58742211; called by muse, mutect2, varscan2
- EYA2 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV57942712; called by muse, mutect2, varscan2
- F8 | c.6407G>A p.G2136E | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM082651, COSV64274473; called by muse, mutect2, varscan2
- FAM241B | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64768472, COSV64768922; called by muse, mutect2
- FANCA | c.2675C>T p.S892F | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.109); catalogued as COSV59796951; called by muse, mutect2, varscan2
- FANCE | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.567); catalogued as COSV100003457; called by muse, mutect2
- FARSB | c.1598A>T p.Y533F | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV56050141; called by muse, mutect2, varscan2
- FBN3 | c.6739G>A p.G2247R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1293892546, COSV54463165; called by muse, mutect2, varscan2
- FER1L6 | c.4490G>A p.G1497E | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV101206181, COSV67549214; called by muse, mutect2, varscan2
- FFAR3 | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as COSV59909173; called by mutect2, varscan2
- FGD5 | c.3810C>T p.I1270= | Splice Region (SNP) | VAF 10/101 reads (10%) | catalogued as rs368487979; called by mutect2, varscan2
- FLG | c.8801A>T p.Q2934L | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100911824; called by muse, mutect2, varscan2
- FLNC | c.7943C>T p.A2648V | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV50800123; called by muse, mutect2, varscan2
- FLRT2 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58143411; called by muse, mutect2, varscan2
- FMNL2 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56496783; called by muse, mutect2, varscan2
- FMO3 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as rs1438077823, COSV63007527; called by muse, mutect2, varscan2
- FOXRED1 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as rs754383840, COSV55007100, COSV99702806; called by muse, mutect2, varscan2
- FRAS1 | c.7131G>A p.M2377I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV53617063; called by muse, mutect2, varscan2
- FSD2 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV58010567; called by muse, mutect2, varscan2
- FUT9 | c.1018C>T p.H340Y | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV56148538; called by muse, mutect2, varscan2
- GABRB3 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as rs1423915719, COSV54668104; called by muse, mutect2, varscan2
- GAP43 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 27/264 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as rs764694995, COSV59342228, COSV59347016; called by muse, mutect2, varscan2
- GBP6 | c.71A>G p.N24S | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV65011624; called by muse, mutect2, varscan2
- GCNT1 | c.532G>T p.V178L | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV65057897; called by muse, mutect2, varscan2
- GGA2 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs764416125, COSV59168862, COSV59170917; called by muse, mutect2, varscan2
- GLCCI1 | c.1271A>C p.E424A | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56202433; called by muse, mutect2, varscan2
- GLT1D1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as rs777988195, COSV55882940; called by muse, mutect2, varscan2
- GLYR1 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.249); catalogued as rs142231403, COSV58926569; called by muse, mutect2, varscan2
- GNPTAB | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV100172182, COSV54776682; called by muse, mutect2, varscan2
- GPATCH8 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as COSV59195357; called by muse, mutect2, varscan2
- GPR139 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs942765597, COSV58501549; called by muse, mutect2, varscan2
- GPR158 | c.1447C>T p.L483F | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66272306; called by muse, mutect2, varscan2
- GPR174 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0.115); catalogued as rs752290236, COSV52132833; called by muse, mutect2, varscan2
- GPR75 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as rs369270021, COSV61828358; called by muse, mutect2, varscan2
- GPSM1 | c.1885C>G p.P629A | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52517717, COSV99396142; called by muse, mutect2, varscan2
- GREB1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs774587906, COSV52189113; called by muse, mutect2, varscan2
- GREB1 | c.4657C>T p.R1553C | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471867130, COSV52189140; called by muse, mutect2, varscan2
- GRID2 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV56174151, COSV56263047; called by muse, mutect2, varscan2
- GRIK5 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV53479801; called by muse, mutect2, varscan2
- GRIN3A | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV62454662; called by muse, mutect2, varscan2
- GSDMA | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.918); catalogued as COSV56976455; called by muse, mutect2, varscan2
- GSS | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53813130; called by muse, mutect2
- GUCY1A2 | c.1427T>C p.L476S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56489206; called by muse, mutect2, varscan2
- HAPLN4 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.565); catalogued as COSV52269925; called by muse, mutect2, varscan2
- HNRNPR | c.712G>A p.G238R | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as COSV56421768; called by muse, mutect2, varscan2
- HOXD8 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.17); catalogued as COSV57485742; called by muse, mutect2, varscan2
- HPS4 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV61103844; called by muse, mutect2, varscan2
- HSPA14 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs1391054423, COSV65684439; called by muse, mutect2, varscan2
- IGHV3-23 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.296); catalogued as rs782495642; called by muse, mutect2
- IGKV2D-30 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs544596031; called by muse, mutect2, varscan2
- IL15RA | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV66092811; called by muse, mutect2, varscan2
- IL17F | c.122T>C p.F41S | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.186); catalogued as COSV60234253; called by muse, mutect2, varscan2
- IL22RA1 | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV54629018; called by muse, mutect2, varscan2
- IL2RB | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV53425402; called by muse, mutect2, varscan2
- IL37 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV54491441; called by muse, mutect2, varscan2
- INTS3 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV59678282; called by muse, mutect2, varscan2
- IQCE | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.606); catalogued as COSV58078953; called by muse, mutect2, varscan2
- ITGA1 | c.2644C>T p.H882Y | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.317); catalogued as COSV50884215; called by muse, mutect2, varscan2
- ITPR1 | c.5866G>A p.D1956N (on ENST00000354582; = p.D1901N on NM_002222.7) | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.247); catalogued as rs982625465, COSV56985240; called by muse, mutect2, varscan2
- JPT1 | c.154T>G p.F52V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV100506787; called by mutect2, varscan2
- KATNB1 | c.1566+1G>A p.X522_splice | Splice Site (SNP) | VAF 14/89 reads (16%) | catalogued as COSV65550832; called by muse, mutect2, varscan2
- KCNB1 | c.2429G>A p.R810K | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.019); catalogued as COSV65568746; called by muse, mutect2, varscan2
- KCNB2 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs756118503, COSV73049946; called by muse, mutect2, varscan2
- KCNH7 | c.2654G>A p.G885E | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV59799394; called by muse, mutect2, varscan2
- KDM3A | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1400664385, COSV57221918; called by muse, mutect2, varscan2
- KIAA0319 | c.2575G>T p.A859S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.53); catalogued as rs1009783487, COSV65499197; called by muse, mutect2, varscan2
- KIAA1109 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52676882; called by muse, mutect2, varscan2
- KIF5A | c.1570-1G>A p.X524_splice | Splice Site (SNP) | VAF 12/43 reads (28%) | catalogued as COSV54055447; called by muse, mutect2, varscan2
- KIR3DL1 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); catalogued as rs374824552; called by muse, mutect2, varscan2
- KIR3DL3 | c.1068G>A p.M356I | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as COSV52548415; called by muse, mutect2, varscan2
- KLHL13 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.2); catalogued as rs267606325, COSV53248919; called by muse, mutect2, varscan2
- KRT26 | c.614C>T p.T205I | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV59413001; called by muse, mutect2, varscan2
- KRT80 | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV100502762; called by muse, mutect2, varscan2
- LAS1L | c.262G>C p.V88L | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV56707669; called by muse, mutect2, varscan2
- LCA5L | c.815A>G p.D272G | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV55745525; called by muse, mutect2, varscan2
- LDLR | c.581G>A p.S194N | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV52943750; called by muse, mutect2, varscan2
- LHFPL4 | c.533T>A p.I178N | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55002523; called by muse, mutect2, varscan2
- LIG1 | c.1424A>T p.E475V | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV54392612; called by muse, mutect2, varscan2
- LILRB4 | c.1147G>A p.E383K (on ENST00000391733 / NM_001278428.3; = p.E382K on NM_001278426.3) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV54404468; called by muse, varscan2
- LRBA | c.6593C>T p.S2198L | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63949422; called by muse, mutect2, varscan2
- LRCH4 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV59643493; called by muse, mutect2, varscan2
- LRFN1 | c.1446C>G p.D482E | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV50451149; called by muse, mutect2, varscan2
- LRIT2 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.549); catalogued as rs776287901, COSV60563108; called by muse, mutect2, varscan2
- LTBP1 | c.4405G>A p.D1469N (on ENST00000404816 / NM_206943.4; = p.D1143N on NM_000627.4) | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.429); catalogued as COSV99698523; called by muse, mutect2, varscan2
- LUM | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs267603717, COSV57127483, COSV57127798; called by muse, mutect2, varscan2
- LY9 | c.1499-1G>A p.X500_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | catalogued as rs1313072077, COSV54434790; called by muse, mutect2, varscan2
- LZTS2 | c.163T>A p.F55I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.036); catalogued as COSV64651813; called by mutect2, varscan2
- MAGEA11 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV60756152; called by muse, varscan2
- MAGI1 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775563326, COSV58330145; called by muse, mutect2, varscan2
- MAK | c.1728G>A p.W576* | Nonsense Mutation (SNP) | VAF 13/110 reads (12%) | catalogued as rs770320899, COSV57565835; called by muse, mutect2, varscan2
- MAN1A1 | c.1210+1G>A p.X404_splice | Splice Site (SNP) | VAF 15/92 reads (16%) | catalogued as COSV63787695; called by muse, mutect2, varscan2
- MAN2B2 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53453659; called by muse, mutect2
- MAP3K4 | c.2291G>C p.S764T | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.047); catalogued as COSV100814941, COSV62334560; called by muse, mutect2, varscan2
- MAST4 | c.4214G>A p.G1405D (on ENST00000403625 / NM_001164664.2; = p.G1216D on NM_015183.3) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55128680; called by muse, mutect2, varscan2
- MCC | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 19/131 reads (15%) | catalogued as rs770384927, COSV68727868; called by muse, mutect2, varscan2
- MCM8 | c.1358T>C p.V453A | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54514814; called by muse, mutect2, varscan2
- MEGF11 | c.1805G>C p.G602A | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1425960361, COSV99988543; called by muse, mutect2, varscan2
- MEGF11 | c.1804G>A p.G602R | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99988549; called by muse, mutect2, varscan2
- MEGF8 | c.1541A>T p.Y514F | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.1); catalogued as COSV52088285; called by muse, mutect2, varscan2
- MEPE | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 20/85 reads (24%) | catalogued as COSV63073058; called by muse, mutect2, varscan2
- MGAM | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs1163875284, COSV72073816; called by muse, mutect2, varscan2
- MGAT5B | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs964424143, COSV56930475, COSV56932699; called by muse, mutect2, varscan2
- MICALL2 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs752846515, COSV52516007; called by muse, mutect2, varscan2
- MLXIP | c.1805C>T p.S602F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV59835715; called by muse, mutect2, varscan2
- MN1 | c.2824G>A p.G942R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (1); catalogued as rs767537756, COSV56559014; called by muse, mutect2
- MORC1 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs1455132472, COSV51716597; called by muse, mutect2, varscan2
- MREG | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV54374362; called by muse, mutect2, varscan2
- MSI2 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52359999; called by muse, mutect2, varscan2
- MTMR3 | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs773832137, COSV60305229; called by muse, mutect2, varscan2
- MUC16 | c.25555T>G p.F8519V | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.046); catalogued as COSV67471957; called by muse, mutect2, varscan2
- MUC16 | c.21748G>A p.E7250K | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.634); catalogued as COSV67471966; called by muse, mutect2, varscan2
- MUC16 | c.19982G>A p.G6661E | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs868263090, COSV67468017; called by muse, mutect2, varscan2
- MUC16 | c.6869C>T p.P2290L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV67471992; called by muse, mutect2, varscan2
- MUC16 | c.1025G>A p.R342K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV67471999; called by muse, mutect2, varscan2
- MXRA5 | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.214); catalogued as COSV54238132; called by muse, mutect2, varscan2
- MYBBP1A | c.3254C>T p.S1085F | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as rs767187903, COSV54598547; called by muse, mutect2, varscan2
- MYH15 | c.5429C>T p.A1810V | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV56311804; called by muse, mutect2, varscan2
- MYH4 | c.4144G>A p.D1382N | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV55119551, COSV55126013; called by muse, mutect2, varscan2
- MYOCD | c.2657C>T p.P886L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58505054; called by muse, mutect2, varscan2
- N4BP2L1 | c.203G>A p.R68K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.237); catalogued as rs1479961504, COSV58413107; called by muse, mutect2, varscan2
- NAMPT | c.1184T>A p.L395* | Nonsense Mutation (SNP) | VAF 20/117 reads (17%) | catalogued as COSV55995344; called by muse, mutect2, varscan2
- NCDN | c.1780G>A p.G594R | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as COSV100622092; called by muse, varscan2
- NCDN | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100622094, COSV61936028; called by muse, varscan2
- NCOR1 | c.6941C>T p.P2314L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV51977913; called by muse, mutect2
- NDST3 | c.779A>C p.D260A | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56620607; called by muse, mutect2, varscan2
- NEB | c.2521G>A p.D841N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs377599060; called by muse, mutect2, varscan2
- NEK4 | c.1696C>T p.R566* | Nonsense Mutation (SNP) | VAF 17/87 reads (20%) | catalogued as rs771482582, COSV51780821; called by muse, mutect2
- NF1 | c.240T>A p.Y80* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as COSV62206317; called by muse, mutect2, varscan2
- NFE2 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 33/182 reads (18%) | catalogued as COSV56456153; called by muse, mutect2, varscan2
- NFIC | c.959-1G>A p.X320_splice | Splice Site (SNP) | VAF 24/119 reads (20%) | catalogued as COSV59413213; called by muse, mutect2, varscan2
- NGFR | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV50802601; called by muse, mutect2, varscan2
- NIBAN1 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100836475; called by muse, mutect2, varscan2
- NME9 | c.674G>A p.G225E (on ENST00000333911 / NM_001349024.2; = p.G164E on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/538 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58619259; called by muse, mutect2, varscan2
- NPAP1 | c.2546G>A p.R849Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs532875296, COSV61504881; called by muse, mutect2, varscan2
- NR3C2 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); catalogued as rs1235702744, COSV60992407; called by muse, mutect2, varscan2
- NREP | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs951060341, COSV57405754; called by muse, mutect2, varscan2
- NREP | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1181688089, COSV57404759; called by muse, mutect2, varscan2
- NRIP1 | c.440T>C p.V147A | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59657892; called by muse, mutect2, varscan2
- NRXN3 | c.3205G>A p.E1069K (on ENST00000335750 / NM_001330195.2; = p.E696K on NM_004796.6) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV59758639; called by muse, mutect2, varscan2
- NSDHL | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV64744206; called by muse, mutect2, varscan2
- NUB1 | c.302A>G p.Y101C | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV63426862; called by muse, mutect2, varscan2
- NUP210L | c.3499G>A p.E1167K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55149423; called by muse, mutect2, varscan2
- NWD1 | c.1031G>A p.G344D | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60343928; called by muse, mutect2, varscan2
- OPRPN | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.298); catalogued as COSV68193005; called by muse, mutect2, varscan2
- OR4K1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV53458965, COSV99578828; called by muse, mutect2, varscan2
- OR51S1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs142743963; called by muse, mutect2, varscan2
- OR52E4 | c.281T>G p.I94S | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV57625088; called by muse, mutect2, varscan2
- OR52E6 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as rs1445038074, COSV61431250; called by muse, mutect2, varscan2
- OR5H14 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV101454298, COSV71194071; called by muse, mutect2, varscan2
- OR8U1 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs753240579, COSV56417115; called by muse, varscan2
- ORC5 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV99857190; called by muse, varscan2
- ORC5 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as COSV99857192; called by muse, mutect2, varscan2
- OSBP2 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60243830; called by muse, mutect2, varscan2
- PCDHA10 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1554150104, COSV56510005; called by muse, mutect2, varscan2
- PCDHA11 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV56510034; called by muse, mutect2, varscan2
- PCDHB10 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.05); catalogued as rs1438920684, COSV53379778; called by muse, mutect2, varscan2
- PCDHB5 | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.056); catalogued as rs781818754, COSV50654544, COSV99167656; called by muse, mutect2, varscan2
- PCDHB7 | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 27/336 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV50760573; called by muse, mutect2
- PCDHGA4 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.358); catalogued as COSV53963819; called by muse, mutect2
- PCLO | c.7823C>T p.S2608L | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV61624551; called by muse, mutect2, varscan2
- PDE1C | c.643G>T p.A215S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.131); catalogued as COSV58516370; called by muse, mutect2, varscan2
- PDZD3 | c.694G>A p.G232S (on ENST00000531114; = p.G166S on NM_024791.4) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.31); PolyPhen probably damaging (1); catalogued as COSV52705521; called by muse, mutect2, varscan2
- PFAS | c.2920C>T p.H974Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs1183737660, COSV58980979; called by muse, mutect2, varscan2
- PGM2 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as COSV67939011; called by muse, mutect2, varscan2
- PIK3R5 | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1426503961, COSV52652249; called by muse, mutect2, varscan2
- PIWIL3 | c.2530C>G p.P844A | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.949); catalogued as rs201599301, COSV59996078; called by muse, mutect2, varscan2
- PKD1 | c.5212C>T p.L1738F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.072); catalogued as rs960035220, COSV51917972; called by muse, mutect2
- PKHD1L1 | c.11990T>C p.I3997T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs1349055785, COSV65744773; called by muse, mutect2, varscan2
- PLEKHG6 | c.539T>C p.L180P | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99164550; called by muse, mutect2, varscan2
- PLIN4 | c.472G>A p.V158M (on ENST00000301286; = p.V173M on NM_001367868.2) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.176); catalogued as rs998673823, COSV100013655; called by muse, mutect2, varscan2
- PLPPR1 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs368320785; called by muse, mutect2, varscan2
- PLXDC2 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV65916249; called by muse, mutect2, varscan2
- PLXNA3 | c.2455C>T p.H819Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV63753747; called by muse, mutect2
- PLXNB2 | c.3013G>A p.G1005S | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100834180; called by muse, mutect2, varscan2
- PMS1 | c.2246C>T p.P749L | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV59716981; called by muse, mutect2, varscan2
- PPIP5K2 | c.3241T>A p.Y1081N | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.412); catalogued as COSV58606209; called by muse, mutect2, varscan2
- PPP1R3A | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756034773, COSV52876023; called by muse, mutect2, varscan2
- PPP4R1 | c.2597T>A p.L866H (on ENST00000400556 / NM_001042388.3; = p.L849H on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53281548; called by muse, mutect2, varscan2
- PPP4R1 | c.2596C>T p.L866F (on ENST00000400556 / NM_001042388.3; = p.L849F on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.285); catalogued as COSV53283415, COSV99553764; called by muse, mutect2, varscan2
- PRB2 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 72/514 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs777631796, COSV101231387, COSV66983306; called by muse, varscan2
- PRDM4 | c.2009G>A p.G670E | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57306062, COSV99946336; called by muse, mutect2, varscan2
- PREX2 | c.4072G>A p.E1358K | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as COSV55775907; called by muse, mutect2, varscan2
- PRICKLE1 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1306531699, COSV61543783; called by muse, mutect2, varscan2
- PRKCB | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57783292, COSV57806070; called by muse, mutect2, varscan2
- PRLR | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.37); catalogued as rs866841150, COSV51493740; called by muse, mutect2, varscan2
- PROKR1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.081); catalogued as COSV58137844; called by muse, mutect2, varscan2
- PRSS12 | c.2452G>C p.V818L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.611); catalogued as COSV56605572, COSV56606950; called by muse, mutect2, varscan2
- PSMD12 | c.860T>C p.V287A | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV62065904; called by muse, mutect2, varscan2
- PSME4 | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs1289745793, COSV66365566; called by muse, mutect2, varscan2
- PTCD3 | c.806A>G p.H269R | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1441309504, COSV54480716; called by muse, mutect2, varscan2
- PTCHD4 | c.1999G>A p.G667S | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as rs781412213, COSV59786645; called by muse, mutect2, varscan2
- PTPRD | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.281); catalogued as rs1354824749, COSV61928182; called by muse, mutect2, varscan2
- RACK1 | c.396G>A p.W132* | Nonsense Mutation (SNP) | VAF 30/168 reads (18%) | catalogued as COSV65174738; called by muse, varscan2
- RAI1 | c.1110T>A p.F370L | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV55394153; called by muse, mutect2, varscan2
- RBMXL1 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV99556615; called by muse, mutect2, varscan2
- REG1A | c.171G>A p.W57* | Nonsense Mutation (SNP) | VAF 35/146 reads (24%) | catalogued as rs772561747, COSV99286861; called by muse, mutect2, varscan2
- REG1A | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs773602919, COSV52070606, COSV52070773; called by muse, mutect2, varscan2
- RETSAT | c.538C>T p.L180F | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1396584405, COSV55526533, COSV55528061; called by muse, varscan2
- RFLNB | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.036); catalogued as rs1000284202, COSV61239497; called by muse, mutect2, varscan2
- RNF152 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV57184134; called by muse, mutect2, varscan2
- RNF213 | c.10546G>A p.G3516R | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV60399648; called by muse, mutect2, varscan2
- RNF216 | c.793G>A p.E265K (on ENST00000425013 / NM_207116.3; = p.E322K on NM_207111.4) | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.202); catalogued as COSV66290873; called by muse, mutect2, varscan2
- RPL10 | c.259A>T p.I87F | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as COSV99186122; called by muse, mutect2, varscan2
- RPL10 | c.260T>C p.I87T | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.415); catalogued as COSV99186123; called by muse, mutect2, varscan2
- RSPH3 | c.458G>A p.R153Q (on ENST00000252655; = p.R11Q on NM_031924.8) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.025); catalogued as rs768608840, COSV51922079, COSV99396415; called by muse, mutect2, varscan2
- RSPH6A | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs777286695, COSV55571044; called by muse, mutect2, varscan2
- RTN2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); catalogued as COSV55594540; called by muse, mutect2, varscan2
- RYR1 | c.6071C>T p.P2024L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100614738, COSV62099697; called by muse, mutect2, varscan2
- SAMD11 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100574682, COSV100574691; called by muse, mutect2, varscan2
- SAMD11 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752886261, COSV100574683; called by muse, mutect2, varscan2
- SCARB1 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.565); catalogued as rs746605995, COSV55548387; called by muse, mutect2, varscan2
- SCN5A | c.2934G>A p.W978* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as rs1553699774, COSV61121981; called by muse, mutect2, varscan2
- SCYL3 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63046155; called by muse, mutect2, varscan2
- SDK1 | c.2869G>A p.G957R | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1281597759, COSV67372413; called by muse, mutect2, varscan2
- SECISBP2 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV60528889; called by muse, mutect2, varscan2
- SETD1A | c.2102C>T p.A701V | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.045); catalogued as COSV52688446; called by muse, varscan2
- SEZ6L | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.965); catalogued as rs758741564, COSV50659876; called by muse, mutect2
- SEZ6L | c.1682-2A>G p.X561_splice | Splice Site (SNP) | VAF 101/293 reads (34%) | catalogued as COSV50667207; called by muse, mutect2, varscan2
- SGCZ | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV65994859; called by muse, mutect2, varscan2
- SIM2 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1234789275, COSV51768758; called by muse, mutect2, varscan2
- SIPA1L3 | c.494C>G p.P165R | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.279); catalogued as COSV55911804, COSV55916187; called by muse, mutect2, varscan2
- SIRT7 | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as rs771395879, COSV58710627, COSV58711491; called by muse, mutect2, varscan2
- SLC10A4 | c.669G>A p.W223* | Nonsense Mutation (SNP) | VAF 38/217 reads (18%) | catalogued as COSV56718972; called by muse, mutect2, varscan2
- SLC12A5 | c.1238C>T p.P413L (on ENST00000454036 / NM_001134771.2; = p.P390L on NM_020708.5) | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV54792176; called by muse, mutect2, varscan2
- SLC14A2 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.096); catalogued as rs753463887, COSV54909869; called by muse, mutect2, varscan2
- SLC15A2 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs754746384, COSV55196531; called by muse, mutect2, varscan2
- SLC15A2 | c.1923G>A p.M641I | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV55197157; called by muse, mutect2, varscan2
- SLC4A11 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV101196076; called by muse, mutect2
- SLC52A2 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV57352202; called by muse, mutect2, varscan2
- SLC6A7 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57938822; called by muse, mutect2, varscan2
- SMARCC1 | c.3274C>T p.P1092S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.039); catalogued as COSV54381830; called by muse, mutect2, varscan2
- SNX29 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763745292, COSV60051004; called by muse, mutect2, varscan2
- SP1 | c.1831G>A p.D611N (on ENST00000327443 / NM_138473.3; = p.D604N on NM_003109.1) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as COSV59403293; called by muse, mutect2, varscan2
- SPAG16 | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1384643936, COSV59073628; called by muse, mutect2, varscan2
- SPATA16 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63529967; called by muse, mutect2, varscan2
- SPATA31E1 | c.3212G>A p.G1071E | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV57792463; called by muse, mutect2, varscan2
- SPATA45 | c.225G>A p.W75* | Nonsense Mutation (SNP) | VAF 19/139 reads (14%) | catalogued as COSV60572089; called by muse, mutect2, varscan2
- SPEF2 | c.4796C>G p.P1599R | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV57429698; called by muse, mutect2, varscan2
- SPIB | c.340-1G>A p.X114_splice | Splice Site (SNP) | VAF 6/39 reads (15%) | catalogued as COSV54531194; called by muse, mutect2, varscan2
- SPTBN5 | c.10744A>T p.K3582* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as rs1304888557, COSV58022342; called by muse, mutect2, varscan2
- SRCAP | c.6115C>T p.Q2039* | Nonsense Mutation (SNP) | VAF 16/157 reads (10%) | catalogued as COSV52674013; called by muse, mutect2, varscan2
- ST7L | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV54145673; called by muse, mutect2, varscan2
- STARD8 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV52923473; called by muse, mutect2, varscan2
- STRC | c.4768C>T p.H1590Y | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV55852713; called by muse, mutect2, varscan2
- SULT1A1 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs776198283, COSV59087012; called by muse, mutect2, varscan2
- SULT4A1 | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50781498; called by muse, varscan2
- TAAR2 | c.830C>T p.P277L (on ENST00000367931 / NM_001033080.1; = p.P232L on NM_014626.3) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51579253; called by muse, mutect2, varscan2
- TAOK1 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.174); catalogued as COSV55588528; called by muse, mutect2, varscan2
- TBC1D1 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54720468; called by muse, mutect2, varscan2
- TBC1D22B | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV65142941; called by muse, mutect2, varscan2
- TBC1D22B | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV65143813; called by muse, mutect2, varscan2
- TBL1XR1 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV61790253; called by muse, mutect2, varscan2
- TBL3 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100224993; called by muse, mutect2, varscan2
- TBL3 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs141126567; called by muse, mutect2, varscan2
- TECPR2 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as COSV63970612, COSV63974405; called by muse, mutect2, varscan2
- TENM1 | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV64424887, COSV64430687; called by muse, mutect2, varscan2
- TENT5C | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1186956228, COSV65616521; called by muse, mutect2, varscan2
- TEP1 | c.3434G>A p.R1145Q | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs747328928, COSV52993984, COSV52995392; called by muse, varscan2
- TFCP2 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56933614; called by muse, mutect2, varscan2
- THSD7B | c.4595G>A p.R1532K (on ENST00000272643; = p.R1530K on NM_001316349.2) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs865978514, COSV55696206; called by muse, mutect2
- TIGD4 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV58548908; called by muse, mutect2, varscan2
- TLN1 | c.6842C>T p.T2281I | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV59208265; called by muse, mutect2, varscan2
- TMCO3 | c.1847G>A p.G616E | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1414649967, COSV64807933, COSV64809670; called by muse, mutect2, varscan2
- TMEM171 | c.478T>C p.F160L | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV55130532; called by muse, varscan2
- TMEM63B | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV52479765; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2212C>T p.P738S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as COSV64101327; called by muse, mutect2, varscan2
- TNPO1 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as COSV61521154, COSV61524573; called by muse, mutect2, varscan2
- TP53BP2 | c.2012C>T p.S671F (on ENST00000343537 / NM_001031685.3; = p.S542F on NM_005426.2) | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV59069206; called by muse, mutect2
- TP63 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53208433; called by muse, mutect2, varscan2
- TRERF1 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV61667692; called by muse, mutect2, varscan2
- TRIP11 | c.2474C>T p.S825L | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV50926270; called by muse, mutect2, varscan2
- TTC7A | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55411901; called by muse, mutect2, varscan2
- TTI1 | c.2179G>A p.D727N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.495); catalogued as COSV65061874; called by muse, mutect2, varscan2
- TTK | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs778540061, COSV57884319; called by muse, mutect2, varscan2
- TTLL6 | c.1345G>A p.E449K (on ENST00000393382 / NM_001130918.3; = p.E142K on NM_173623.3) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as COSV64977550; called by muse, mutect2, varscan2
- TTN | c.60136G>A p.G20046R (on ENST00000591111; = p.G12622R on NM_003319.4) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | PolyPhen probably damaging (1); catalogued as COSV60114345; called by muse, mutect2, varscan2
- TTN | c.12739G>A p.E4247K (on ENST00000591111; = p.E4201K on NM_003319.4) | Missense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as rs746672079, COSV60169973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 16/100 reads (16%) | PolyPhen probably damaging (0.998); catalogued as COSV60114394; called by muse, mutect2, varscan2
- TUBA3D | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as rs553840291, COSV100342734; called by muse, mutect2, varscan2
- TUBB6 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1453031162, COSV52315024; called by muse, mutect2, varscan2
- TUBGCP2 | c.2375C>T p.A792V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV53302548, COSV99428067; called by muse, mutect2, varscan2
- TULP4 | c.3155C>T p.S1052F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.019); catalogued as COSV65576485; called by muse, mutect2, varscan2
- UBE3D | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52758001; called by muse, mutect2, varscan2
- UBXN1 | c.229T>A p.S77T | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV53657593; called by muse, mutect2, varscan2
- UMODL1 | c.3686A>G p.K1229R (on ENST00000408910 / NM_001004416.2; = p.K1357R on NM_173568.3) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.101); catalogued as COSV68570073; called by muse, varscan2
- UNC5D | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV54801078; called by muse, mutect2, varscan2
- UNC93A | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs775029585, COSV100023480; called by muse, mutect2, varscan2
- URB2 | c.1777C>G p.P593A | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV99271547; called by muse, mutect2, varscan2
- URB2 | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV99271551; called by muse, mutect2, varscan2
- USH2A | c.14156G>A p.G4719E | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56341510; called by muse, mutect2, varscan2
- USH2A | c.7466C>T p.P2489L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56381423; called by muse, mutect2, varscan2
- USP29 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs954305714, COSV54143387; called by muse, mutect2, varscan2
- UVRAG | c.1858G>A p.V620I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.01); catalogued as COSV62105138; called by muse, mutect2, varscan2
- VDAC1 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV54737538; called by muse, mutect2, varscan2
- VGLL3 | c.24T>A p.Y8* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV67353198; called by muse, mutect2, varscan2
- VPS13B | c.11302G>A p.G3768S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745652006, COSV62144994; called by muse, mutect2
- VTN | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs112195186, COSV52647014; called by mutect2, varscan2
- VWCE | c.1255G>A p.V419M | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.373); catalogued as COSV57112911; called by muse, mutect2, varscan2
- WDR11 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs867397877, COSV54788054; called by muse, mutect2, varscan2
- WDR20 | c.901C>T p.H301Y | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV100085286; called by muse, mutect2, varscan2
- WDR46 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764950576, COSV65851705; called by muse, mutect2, varscan2
- WDR49 | c.1909A>G p.K637E (on ENST00000308378 / NM_001366158.1; = p.K978E on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/300 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV57709609; called by muse, mutect2
- WDR64 | c.1622G>A p.G541E | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.209); catalogued as COSV63796738; called by muse, mutect2, varscan2
- WNK4 | c.720G>A p.W240* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV53820951; called by mutect2, varscan2
- WRNIP1 | c.875T>A p.F292Y | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.267); catalogued as COSV66356118; called by muse, mutect2, varscan2
- WSCD2 | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374705143; called by mutect2, varscan2
- XIRP1 | c.3989C>T p.P1330L | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61138990; called by muse, mutect2, varscan2
- XYLT1 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs1421269660, COSV54486307; called by muse, mutect2, varscan2
- YEATS2 | c.2639C>T p.S880L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV100528085; called by muse, mutect2, varscan2
- ZBTB39 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100268123; called by muse, mutect2, varscan2
- ZBTB7B | c.206G>A p.G69E (on ENST00000292176; = p.G103E on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52693005; called by muse, mutect2, varscan2
- ZFP41 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV58087617; called by muse, mutect2, varscan2
- ZFP42 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs866099446, COSV58817784; called by muse, mutect2, varscan2
- ZNF14 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); catalogued as COSV59849919; called by muse, mutect2, varscan2
- ZNF230 | c.1072C>T p.H358Y | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV71273456; called by muse, mutect2, varscan2
- ZNF28 | c.1801C>T p.H601Y | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60423510; called by muse, mutect2, varscan2
- ZNF354C | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | catalogued as COSV59608541; called by muse, mutect2, varscan2
- ZNF385A | c.298C>T p.R100* (on ENST00000338010 / NM_001130967.3; = p.R80* on NM_015481.3) | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV100566947; called by muse, mutect2, varscan2
- ZNF429 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 19/114 reads (17%) | catalogued as COSV100641991; called by muse, mutect2, varscan2
- ZNF831 | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs780345393, COSV64041178; called by muse, mutect2, varscan2
- CHRD | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DAW1 | c.110_111del p.P37Qfs*3 | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | called by muse*, mutect2, varscan2*
- HMG20A | c.354del p.E119Nfs*19 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | called by mutect2, pindel*, varscan2
- INTS13 | c.662_665del p.R221Lfs*9 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | called by mutect2, pindel, varscan2
- PAPOLA | c.372del p.D125Ifs*13 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- PLEKHG3 | c.1175C>T p.S392F (on ENST00000394691; = p.S448F on NM_001308147.2) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PYGO2 | c.1090_1091del p.S364Rfs*8 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | called by pindel, varscan2
- RANBP10 | c.1060C>T p.R354* | Nonsense Mutation (SNP) | VAF 22/127 reads (17%) | called by muse, mutect2
- SET | c.486dup p.D163* (on ENST00000372692 / NM_001374326.1; = p.D150* on NM_003011.4) | Frame Shift Ins (INS) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- SLC13A4 | c.522del p.E175Rfs*9 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | called by mutect2, pindel, varscan2
- TEP1 | c.3462del p.Q1154Hfs*3 | Frame Shift Del (DEL) | VAF 14/79 reads (18%) | called by pindel, varscan2
- WIF1 | c.429del p.K143Nfs*12 | Frame Shift Del (DEL) | VAF 17/85 reads (20%) | called by mutect2, pindel, varscan2
- ABCB1 | c.423A>G p.G141= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV55953339; called by muse, mutect2, varscan2
- ABCC12 | c.3597G>A p.V1199= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV60914536; called by muse, mutect2, varscan2
- ABCE1 | c.33C>T p.V11= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV56847483; called by mutect2, varscan2
- ACTL9 | c.1137C>T p.S379= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs548848075, COSV100185545, COSV61006062; called by muse, varscan2
- ADAM18 | c.1977C>T p.S659= | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as COSV55848736; called by muse, mutect2, varscan2
- ADGRF5 | c.438C>T p.L146= | Silent (SNP) | VAF 25/128 reads (20%) | catalogued as COSV51935061; called by muse, mutect2, varscan2
- ADGRG4 | c.2241C>T p.S747= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV54958199; called by muse, mutect2, varscan2
- AKAP13 | c.4395C>T p.A1465= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs760274881, COSV63363218; called by muse, mutect2, varscan2
- AKAP6 | c.936T>A p.A312= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs1566566621, COSV55216593; called by mutect2, varscan2
- ANK1 | c.411G>A p.Q137= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV55883790; called by muse, mutect2, varscan2
- ANK3 | c.3636C>T p.F1212= (on ENST00000280772 / NM_001320874.2; = p.F346= on NM_001149.3) | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV55061843; called by muse, mutect2, varscan2
- AP1M2 | c.768C>T p.I256= | Silent (SNP) | VAF 25/131 reads (19%) | catalogued as COSV51567555; called by muse, mutect2, varscan2
- ARID2 | c.2391A>T p.P797= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100536550; called by muse, mutect2, varscan2
- ASB10 | c.1305C>T p.S435= (on ENST00000420175 / NM_001142459.2; = p.S420= on NM_080871.4) | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs138510080; called by muse, mutect2
- ASXL1 | c.1578C>T p.S526= | Silent (SNP) | VAF 27/211 reads (13%) | catalogued as COSV60104712; called by muse, mutect2, varscan2
- ATP8B2 | c.1410C>T p.S470= (on ENST00000672630; = p.S437= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs992225720, COSV59246470; called by muse, mutect2, varscan2
- AZU1 | c.747G>A p.G249= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV52141272; called by muse, mutect2, varscan2
- B4GALNT3 | c.2925C>T p.S975= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1488137283, COSV56753376; called by muse, varscan2
- BCAR3 | c.453C>T p.S151= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV53075860; called by muse, mutect2, varscan2
- BCLAF1 | c.951C>T p.G317= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV62142780; called by mutect2, varscan2
- BEND3 | c.954G>A p.V318= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV64681316; called by muse, mutect2, varscan2
- BRINP3 | c.1806C>T p.D602= | Silent (SNP) | VAF 43/255 reads (17%) | catalogued as COSV66527099; called by muse, mutect2, varscan2
- C1orf94 | c.663G>A p.G221= (on ENST00000488417 / NM_001134734.2; = p.G31= on NM_032884.5) | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV64914285; called by muse, mutect2, varscan2
- C9orf152 | c.90C>T p.A30= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs764327257, COSV68762924; called by muse, mutect2, varscan2
- CAPN2 | c.1162C>T p.L388= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV54336765; called by muse, mutect2, varscan2
- CCT8L2 | c.918G>A p.L306= | Silent (SNP) | VAF 50/332 reads (15%) | catalogued as COSV63462784; called by muse, mutect2, varscan2
- CD163 | c.3195C>T p.F1065= | Silent (SNP) | VAF 30/135 reads (22%) | catalogued as rs763870346, COSV63129316; called by muse, mutect2, varscan2
- CD4 | c.168C>T p.S56= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV50591662; called by muse, mutect2, varscan2
- CDH24 | c.1977C>T p.F659= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs777087751, COSV57461634; called by muse, mutect2, varscan2
- CDHR3 | c.2265G>A p.K755= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as COSV58418006; called by muse, mutect2, varscan2
- CELSR3 | c.2700C>T p.N900= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs777752288, COSV50879752; called by muse, mutect2, varscan2
- CFAP65 | c.4380C>T p.L1460= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV58562016; called by muse, mutect2, varscan2
- CHRD | c.894G>A p.G298= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as rs931125688, COSV52614481; called by muse, mutect2, varscan2
- CILP2 | c.1881C>T p.F627= | Silent (SNP) | VAF 25/133 reads (19%) | catalogued as rs750737180, COSV52275894; called by muse, mutect2, varscan2
- CLCN5 | c.1368C>T p.I456= | Silent (SNP) | VAF 60/176 reads (34%) | catalogued as COSV56584597; called by muse, mutect2, varscan2
- CLEC12A | c.39G>A p.Q13= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as COSV58561454; called by muse, mutect2, varscan2
- CNTNAP2 | c.3561C>T p.I1187= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs775209615, COSV62192752, COSV62265806; called by muse, mutect2, varscan2
- CNTNAP2 | c.3844C>T p.L1282= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV62177641; called by muse, mutect2
- COL11A2 | c.2094C>T p.P698= (on ENST00000341947 / NM_080680.3; = p.P591= on NM_080679.2) | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV59497909; called by muse, mutect2
- CRX | c.363G>A p.A121= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs141888455; called by muse, mutect2, varscan2
- CSNK2A1 | c.687G>A p.K229= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV53935476; called by muse, mutect2, varscan2
- CTBP1 | c.795C>T p.A265= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV52074504; called by muse, mutect2
- CTSA | c.897G>A p.Q299= | Silent (SNP) | VAF 31/156 reads (20%) | catalogued as COSV99510032; called by muse, mutect2, varscan2
- CWH43 | c.2099G>A p.*700= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV56936195; called by muse, mutect2, varscan2
- DAB1 | c.915C>T p.I305= (on ENST00000371231; = p.I272= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV64692613; called by muse, mutect2, varscan2
- DAW1 | c.108T>A p.G36= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV100006354; called by muse, varscan2
- DCST2 | c.351C>T p.T117= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV55052275; called by muse, mutect2, varscan2
- DDC | c.771C>T p.V257= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as rs117436059; called by muse, mutect2, varscan2
- DERA | c.249C>T p.L83= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV70774535; called by muse, mutect2, varscan2
- DIPK2B | c.1155C>T p.I385= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV67641214; called by muse, mutect2, varscan2
- DIS3L2 | c.945C>T p.A315= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as rs747141045, COSV56056112; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNM1 | c.1143G>A p.E381= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV57852325; called by muse, mutect2, varscan2
- DOK2 | c.966T>A p.P322= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV99374832; called by muse, mutect2, varscan2
- DPYSL5 | c.90C>T p.I30= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs144960416; called by mutect2, varscan2
- DYNC1I1 | c.1740C>T p.A580= | Silent (SNP) | VAF 49/140 reads (35%) | catalogued as COSV61462469; called by muse, mutect2, varscan2
- EEF2KMT | c.366C>T p.L122= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV69863487; called by muse, mutect2, varscan2
- EFEMP2 | c.1227G>A p.R409= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV57260404; called by muse, mutect2, varscan2
- ESRP1 | c.1068G>A p.K356= | Silent (SNP) | VAF 82/544 reads (15%) | catalogued as COSV64412019; called by muse, mutect2, varscan2
- F13A1 | c.189G>A p.V63= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs201149092, COSV53560124; called by muse, mutect2, varscan2
- FAM47B | c.915C>T p.S305= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs377737946, COSV61454438; called by muse, varscan2
- FAM81B | c.807G>A p.K269= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV51983520; called by muse, mutect2, varscan2
- FANCE | c.651C>T p.P217= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100003458; called by muse, mutect2, varscan2
- FAT3 | c.882G>A p.A294= | Silent (SNP) | VAF 135/638 reads (21%) | catalogued as rs200428460, COSV53121432; called by muse, mutect2, varscan2
- FGL2 | c.222G>A p.R74= | Silent (SNP) | VAF 26/148 reads (18%) | catalogued as COSV50382315; called by muse, mutect2, varscan2
- FLOT2 | c.303C>T p.N101= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as rs769141868, COSV67528851; called by mutect2, varscan2
- FMOD | c.36C>T p.L12= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs1471901967, COSV61610142; called by muse, mutect2, varscan2
- FSIP2 | c.19272C>T p.S6424= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs558745255, COSV58083589; called by muse, mutect2, varscan2
- FUS | c.285C>T p.S95= | Silent (SNP) | VAF 25/174 reads (14%) | catalogued as rs762095418, COSV54217441; called by muse, mutect2, varscan2
- GABRG2 | c.1266C>T p.I422= (on ENST00000361925 / NM_001375343.1; = p.I382= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV62718775; called by muse, mutect2, varscan2
- GABRG3 | c.561G>A p.L187= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV61520468; called by muse, mutect2, varscan2
- GABRP | c.648C>T p.F216= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV54663344; called by muse, mutect2, varscan2
- GAP43 | c.663C>T p.A221= | Silent (SNP) | VAF 28/267 reads (10%) | catalogued as COSV100525764; called by muse, mutect2, varscan2
- GEMIN5 | c.3681C>T p.L1227= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV53561321; called by muse, mutect2, varscan2
- GMDS | c.813C>T p.F271= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs149057214; called by muse, mutect2, varscan2
- GPR50 | c.591C>T p.F197= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as rs760767794, COSV54439449; called by muse, varscan2
- GRIN2A | c.3879T>C p.D1293= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as rs1199650629, COSV58037286; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRIN2B | c.2037C>T p.P679= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV74206246, COSV74206652; called by muse, mutect2
- GYPA | c.318G>A p.T106= | Silent (SNP) | VAF 39/218 reads (18%) | catalogued as rs749616078, COSV51618752, COSV51626553, COSV99301501; called by muse, mutect2, varscan2
- HERC1 | c.330C>G p.L110= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as COSV71248175; called by muse, mutect2, varscan2
- HINFP | c.381C>T p.D127= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV63432145; called by muse, mutect2, varscan2
- HJV | c.738C>T p.A246= (on ENST00000336751 / NM_213653.4; = p.A133= on NM_145277.5) | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV60952286; called by muse, mutect2, varscan2
- HOXB5 | c.591C>T p.A197= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs1165142106, COSV53313267; called by muse, mutect2
- HYDIN | c.14097G>A p.E4699= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV66639479; called by muse, varscan2
- IARS2 | c.2598T>A p.T866= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV56960417; called by muse, mutect2, varscan2
- IGHG3 | c.858G>A p.E286= | Silent (SNP) | VAF 43/272 reads (16%) | called by muse, mutect2, varscan2
- IGKV3-7 | c.207C>T p.I69= | Silent (SNP) | VAF 27/92 reads (29%) | called by muse, mutect2, varscan2
- IGKV6D-41 | c.87T>A p.A29= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- IL27RA | c.309C>T p.L103= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV54601296; called by muse, varscan2
- IQGAP3 | c.3369C>T p.L1123= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as rs1342346496, COSV63252189; called by muse, mutect2, varscan2
- ITGAX | c.1629C>T p.A543= | Silent (SNP) | VAF 52/206 reads (25%) | catalogued as COSV51642194, COSV51646706; called by muse, mutect2, varscan2
- ITPRIPL1 | c.459C>T p.V153= (on ENST00000439118 / NM_001008949.3; = p.V161= on NM_178495.6) | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs1423589374, COSV63153737; called by muse, mutect2, varscan2
- JADE1 | c.1176C>T p.S392= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as rs878888918, COSV56906491; called by muse, mutect2, varscan2
- JCAD | c.1845G>A p.K615= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs1276789267, COSV64760046; called by muse, mutect2, varscan2
- KAT14 | c.2190G>A p.K730= | Silent (SNP) | VAF 33/181 reads (18%) | catalogued as COSV66607996; called by muse, varscan2
- KCNH2 | c.1803C>T p.G601= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV51175810; called by muse, mutect2, varscan2
- KCNK2 | c.447C>T p.F149= (on ENST00000444842 / NM_001017425.3; = p.F134= on NM_014217.4) | Silent (SNP) | VAF 24/183 reads (13%) | catalogued as COSV67206741; called by muse, mutect2, varscan2
- KIF1A | c.81C>T p.I27= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV57491749; called by mutect2, varscan2
- KLHDC7A | c.429G>A p.Q143= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV68770023; called by muse, mutect2, varscan2
- KLHL15 | c.1768C>T p.L590= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs776903969, COSV60140580; called by muse, mutect2, varscan2
- KRT80 | c.235C>T p.L79= | Silent (SNP) | VAF 16/110 reads (15%) | catalogued as COSV100502763, COSV57547584; called by muse, mutect2, varscan2
- KRTAP10-9 | c.127C>T p.L43= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV59965939; called by muse, mutect2, varscan2
- LAMA3 | c.4080G>A p.R1360= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV58070352; called by muse, mutect2, varscan2
- LAMA3 | c.8172G>A p.R2724= (on ENST00000313654 / NM_198129.4; = p.R1115= on NM_000227.6) | Silent (SNP) | VAF 26/141 reads (18%) | catalogued as COSV52535989; called by muse, mutect2, varscan2
- LDLR | c.1233G>A p.K411= | Silent (SNP) | VAF 58/309 reads (19%) | catalogued as rs1281544784, CD984594, COSV52943761; called by muse, mutect2, varscan2
- LGR5 | c.807C>T p.I269= | Silent (SNP) | VAF 76/424 reads (18%) | catalogued as COSV57005703; called by muse, mutect2, varscan2
- LGR6 | c.177C>T p.A59= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs755510131, COSV66157090; called by muse, mutect2
- LIFR | c.2664C>T p.V888= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as COSV54691694; called by muse, mutect2
- LILRB1 | c.759C>T p.L253= (on ENST00000427581; = p.L217= on NM_006669.6) | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as COSV61118836; called by muse, varscan2
- LIPF | c.903G>A p.G301= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV53284168; called by muse, mutect2, varscan2
- LRRC2 | c.174C>T p.I58= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV56126478; called by muse, mutect2, varscan2
- LRRIQ3 | c.534C>T p.N178= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs144700840; called by muse, mutect2
- LRRTM4 | c.1725C>T p.I575= | Silent (SNP) | VAF 45/232 reads (19%) | catalogued as rs748303965, COSV69150918, COSV69164716; called by muse, mutect2, varscan2
- LRTM1 | c.873C>T p.I291= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV55546292; called by muse, mutect2, varscan2
- LRTM1 | c.45C>T p.L15= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV55546301; called by muse, mutect2
- LYPLA2 | c.540C>T p.P180= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs540641459, COSV100994833, COSV65720725; called by muse, mutect2, varscan2
- MAP3K20 | c.2109C>T p.S703= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV64378652; called by muse, mutect2, varscan2
- MARS1 | c.723G>A p.E241= | Silent (SNP) | VAF 30/161 reads (19%) | catalogued as COSV56255513; called by muse, mutect2, varscan2
- MIA2 | c.1410C>T p.F470= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV54482261; called by muse, mutect2, varscan2
- MNDA | c.27T>A p.L9= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV63741033; called by muse, mutect2, varscan2
- MRPL41 | c.255C>T p.P85= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1360564592, COSV53000144; called by muse, mutect2, varscan2
- MTUS2 | c.1857G>A p.Q619= | Silent (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2
- MYH1 | c.3015G>A p.E1005= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as rs1177928073, COSV56846193; called by muse, mutect2
- MYH14 | c.4923A>G p.G1641= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV51820503; called by muse, mutect2
- MYH8 | c.3537G>A p.R1179= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV67966427, COSV67970896; called by muse, mutect2, varscan2
- MYO1D | c.204C>T p.G68= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV59015195; called by muse, mutect2, varscan2
- MYOF | c.5625G>A p.T1875= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs771670858, COSV63705333; called by mutect2, varscan2
- NAT10 | c.2298C>T p.A766= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as rs113424951, COSV57664304; called by muse, mutect2, varscan2
- NBR1 | c.1647C>T p.I549= | Silent (SNP) | VAF 50/185 reads (27%) | catalogued as rs1397721809, COSV57833029; called by muse, mutect2, varscan2
- NFKBIB | c.723C>T p.G241= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as rs1257423971, COSV100548444; called by muse, mutect2
- NIBAN1 | c.1926C>T p.L642= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV62282895; called by muse, mutect2, varscan2
- NIPSNAP1 | c.486G>A p.R162= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as rs752291408, COSV53342828; called by muse, mutect2, varscan2
- NLRP1 | c.2019C>T p.F673= | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as COSV52568266; called by muse, mutect2, varscan2
- NLRP13 | c.690G>A p.T230= | Silent (SNP) | VAF 32/148 reads (22%) | catalogued as rs574504902, COSV61619992; called by muse, mutect2, varscan2
- NNMT | c.357G>A p.G119= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs747266840, COSV55474024; called by muse, mutect2, varscan2
- NOTCH1 | c.6420C>T p.C2140= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV53057811; called by muse, mutect2
- NRCAM | c.1536T>A p.I512= (on ENST00000379028 / NM_001371124.1; = p.I506= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as COSV61038969; called by muse, mutect2, varscan2
- NTRK3 | c.1749G>A p.K583= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as rs769177961, COSV62307141; called by muse, mutect2, varscan2
- NUP205 | c.5541C>T p.P1847= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs370401064; called by muse, mutect2
- NUP93 | c.1611G>A p.R537= | Silent (SNP) | VAF 47/161 reads (29%) | catalogued as COSV57430990, COSV57431393; called by muse, mutect2, varscan2
- NWD1 | c.3633T>C p.F1211= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV60343950; called by muse, mutect2, varscan2
- OR10G7 | c.112C>T p.L38= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV57867449; called by muse, mutect2, varscan2
- OR10G9 | c.112C>T p.L38= | Silent (SNP) | VAF 16/172 reads (9%) | catalogued as COSV66686374; called by muse, mutect2
- OR10Z1 | c.879G>A p.R293= | Silent (SNP) | VAF 47/278 reads (17%) | catalogued as rs781215502, COSV63525122; called by muse, mutect2, varscan2
- OR11H1 | c.417C>T p.I139= | Silent (SNP) | VAF 11/41 reads (27%) | called by mutect2, varscan2
- OR11H12 | c.123C>T p.F41= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as rs747747275, COSV73543554, COSV73543671; called by muse, mutect2, varscan2
- OR4D9 | c.282C>T p.F94= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV61434826; called by muse, mutect2, varscan2
- OR5M1 | c.813C>T p.S271= | Silent (SNP) | VAF 47/208 reads (23%) | catalogued as COSV73202187; called by muse, mutect2, varscan2
- OR5P3 | c.129C>T p.I43= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs1335031350, COSV60429384; called by muse, mutect2, varscan2
- OR7C2 | c.771C>T p.V257= | Silent (SNP) | VAF 29/133 reads (22%) | catalogued as COSV50180864; called by muse, mutect2, varscan2
- OR8G1 | c.249G>A p.V83= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as rs367900630; called by mutect2, varscan2
- OSBPL10 | c.1077C>T p.T359= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV67340139; called by muse, mutect2, varscan2
- OTOGL | c.4434T>C p.F1478= (on ENST00000547103; = p.F1469= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV54017841; called by muse, mutect2, varscan2
- PARP16 | c.477C>T p.F159= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV56035497; called by muse, varscan2
- PCDHB11 | c.180C>T p.S60= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV53379780; called by muse, mutect2, varscan2
- PCDHGA1 | c.250T>C p.L84= | Silent (SNP) | VAF 35/204 reads (17%) | catalogued as COSV65297005; called by muse, mutect2, varscan2
- PCDHGC5 | c.2175G>A p.G725= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as COSV52754524; called by muse, mutect2, varscan2
- PDZD2 | c.6849G>A p.L2283= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV56860619; called by muse, mutect2, varscan2
- PHB2 | c.9G>A p.Q3= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV54642279; called by muse, varscan2
- PHF1 | c.57T>G p.A19= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV65702867; called by muse, mutect2, varscan2
- PIK3R2 | c.1185C>T p.F395= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV55848368; called by muse, mutect2, varscan2
- PKD1L1 | c.8541G>A p.K2847= | Silent (SNP) | VAF 59/179 reads (33%) | catalogued as COSV56967411; called by muse, mutect2, varscan2
- PKP4 | c.3105G>A p.Q1035= | Silent (SNP) | VAF 31/156 reads (20%) | catalogued as COSV61578963; called by muse, mutect2, varscan2
- PLA2G6 | c.252C>T p.F84= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs765050084, COSV59270323; called by muse, mutect2, varscan2
- PLCH1 | c.3813G>A p.T1271= (on ENST00000340059 / NM_001130960.2; = p.T1263= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/178 reads (11%) | catalogued as rs766465810, COSV58190024; called by muse, mutect2, varscan2
- PLEKHG6 | c.540C>T p.L180= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99164555; called by mutect2, varscan2
- PLIN4 | c.471G>A p.T157= (on ENST00000301286; = p.T172= on NM_001367868.2) | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs756341953, COSV100013660; called by mutect2, varscan2
- PLPP2 | c.39G>C p.L13= | Silent (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- PLXNB2 | c.3012G>A p.T1004= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as rs1397156243, COSV100834181; called by muse, mutect2
- PRKG2 | c.840C>T p.F280= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV52325376; called by muse, mutect2, varscan2
- PROKR1 | c.162T>C p.N54= | Silent (SNP) | VAF 32/173 reads (18%) | catalogued as rs1204091629, COSV58137852; called by muse, mutect2, varscan2
- PRRC2C | c.8139C>T p.F2713= (on ENST00000367742; = p.F2711= on NM_015172.4) | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV58906703; called by muse, mutect2, varscan2
- PRSS58 | c.132C>T p.V44= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV73488535; called by muse, mutect2, varscan2
- PSG8 | c.456C>T p.S152= | Silent (SNP) | VAF 40/222 reads (18%) | catalogued as COSV60612516, COSV60616168; called by muse, mutect2, varscan2
- PTCHD3 | c.153G>A p.P51= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as rs1386975242, COSV71256764, COSV71257170; called by muse, mutect2, varscan2
- RANBP10 | c.1059C>T p.S353= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV100449383; called by muse, mutect2, varscan2
- RBMXL1 | c.1047C>T p.P349= | Silent (SNP) | VAF 26/203 reads (13%) | catalogued as COSV99556614; called by muse, mutect2, varscan2
- RELCH | c.2700G>A p.G900= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs780298090, COSV56886563, COSV99901966; called by muse, mutect2
- RNF165 | c.663T>C p.L221= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV53974189; called by muse, mutect2, varscan2
- RPE65 | c.672G>A p.E224= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV52016557; called by muse, mutect2, varscan2
- RPIA | c.645C>T p.I215= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs1228525768, COSV52170029; called by muse, mutect2, varscan2
- RTL9 | c.1887G>A p.T629= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs1231200854, COSV71825699; called by muse, mutect2, varscan2
- RUNX2 | c.1005G>A p.V335= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs1164494556, COSV61841897; called by muse, mutect2
- SALL4 | c.1230C>T p.F410= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs1193747049, COSV53852826; called by muse, mutect2, varscan2
- SAP130 | c.2490C>T p.A830= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as rs1394271849, COSV52098261; called by muse, mutect2, varscan2
- SCAMP1 | c.702C>T p.L234= | Silent (SNP) | VAF 20/203 reads (10%) | catalogued as COSV57240890; called by muse, mutect2, varscan2
- SCNN1G | c.1737C>T p.P579= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as rs767251358, COSV55599366; called by muse, mutect2, varscan2
- SH3BP5 | c.681G>A p.K227= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV53744676, COSV53747455; called by muse, mutect2
- SHROOM3 | c.5550C>T p.S1850= | Silent (SNP) | VAF 25/140 reads (18%) | catalogued as COSV56024159; called by muse, mutect2, varscan2
- SIPA1L1 | c.5169G>A p.Q1723= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as rs763382333, COSV62170823; called by muse, mutect2, varscan2
- SIRPG | c.780C>T p.P260= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV53807959; called by muse, mutect2, varscan2
- SKIV2L | c.2790C>T p.T930= | Silent (SNP) | VAF 37/213 reads (17%) | catalogued as COSV61713886; called by muse, mutect2, varscan2
- SKP1 | c.15G>A p.K5= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV60435842; called by muse, mutect2, varscan2
- SLC25A17 | c.135C>T p.S45= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV54351476; called by muse, mutect2, varscan2
- SLC25A47 | c.504G>A p.T168= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1018798373, COSV100690242; called by muse, mutect2, varscan2
- SLC2A7 | c.486G>A p.K162= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV101280812; called by muse, mutect2, varscan2
- SLC35B4 | c.879C>T p.T293= | Silent (SNP) | VAF 42/169 reads (25%) | catalogued as rs778788380, COSV65984870; called by muse, mutect2, varscan2
- SLC44A5 | c.2037C>T p.F679= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs779916778, COSV63766826; called by muse, mutect2, varscan2
- SLC46A1 | c.1371G>A p.Q457= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV50229478; called by muse, mutect2, varscan2
- SLC8A2 | c.279C>T p.F93= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV52637905, COSV52641989; called by muse, mutect2, varscan2
- SLITRK1 | c.1059G>A p.S353= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs1327875339, COSV65676119; called by muse, varscan2
- SMG9 | c.114G>A p.E38= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV54214876; called by muse, varscan2
- SNRNP200 | c.5544C>T p.I1848= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV55530935; called by muse, mutect2, varscan2
- SNX5 | c.291C>T p.P97= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as rs375257051; called by muse, mutect2, varscan2
- SPDYE1 | c.90G>A p.R30= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV99324040; called by muse, mutect2, varscan2
- ST14 | c.2430C>T p.S810= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV53833882; called by muse, mutect2
- ST6GALNAC3 | c.201G>A p.V67= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV60335278; called by muse, mutect2, varscan2
- STK10 | c.2016C>T p.P672= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV51574855; called by muse, mutect2, varscan2
- STK11IP | c.3147C>T p.L1049= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV55250768; called by muse, mutect2, varscan2
- STOX1 | c.651C>T p.S217= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV53815390; called by muse, mutect2, varscan2
- SVIL | c.1635C>T p.T545= | Silent (SNP) | VAF 28/165 reads (17%) | catalogued as COSV63444169; called by muse, mutect2, varscan2
- SYNPO2 | c.3657T>C p.Y1219= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV61112096; called by muse, mutect2, varscan2
- TAGLN3 | c.289C>T p.L97= | Silent (SNP) | VAF 31/203 reads (15%) | catalogued as COSV56327744; called by muse, mutect2, varscan2
- TAS2R38 | c.414G>A p.R138= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV71885394; called by muse, mutect2, varscan2
- TIGD3 | c.1152C>T p.P384= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as rs780734660, COSV52889708; called by muse, mutect2, varscan2
- TLR4 | c.1461C>T p.F487= (on ENST00000355622 / NM_138554.5; = p.F447= on NM_003266.4) | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV62923054; called by muse, mutect2, varscan2
- TMC7 | c.883C>T p.L295= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs528211641, COSV58584147; called by muse, mutect2, varscan2
- TMCO5A | c.792G>A p.R264= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as COSV60465000; called by muse, mutect2, varscan2
- TMEM38B | c.780A>G p.A260= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV65949329; called by muse, mutect2, varscan2
- TNXB | c.345G>A p.K115= | Silent (SNP) | VAF 66/276 reads (24%) | catalogued as COSV64480422; called by muse, mutect2, varscan2
- TP53I11 | c.315C>T p.L105= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV57533370; called by muse, mutect2
- TP53I3 | c.933G>A p.Q311= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV51981095; called by muse, mutect2, varscan2
- TP63 | c.621G>A p.K207= | Silent (SNP) | VAF 25/187 reads (13%) | catalogued as COSV53208461, COSV99288404; called by muse, mutect2, varscan2
- TRAPPC3 | c.372C>T p.S124= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV64264410; called by muse, mutect2, varscan2
- TRIM26 | c.595C>T p.L199= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV68963146; called by muse, mutect2, varscan2
- TRIML2 | c.1086C>T p.F362= | Silent (SNP) | VAF 31/205 reads (15%) | catalogued as rs1313602886, COSV58716734; called by muse, varscan2
- TRPC5 | c.1017C>T p.F339= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV53292835; called by muse, mutect2, varscan2
- TTLL6 | c.1344G>A p.L448= (on ENST00000393382 / NM_001130918.3; = p.L141= on NM_173623.3) | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs371747543; called by muse, mutect2, varscan2
- TUBA3D | c.528G>A p.Q176= | Silent (SNP) | VAF 37/235 reads (16%) | catalogued as rs778580729, COSV100342730; called by muse, mutect2, varscan2
- TUBG2 | c.1167A>G p.E389= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV52218024; called by muse, mutect2, varscan2
- UGT2B17 | c.39G>A p.Q13= | Silent (SNP) | VAF 69/393 reads (18%) | catalogued as rs376751040; called by mutect2, varscan2
- UNC13A | c.2115C>T p.V705= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs372628249; called by muse, mutect2, varscan2
- UNC5A | c.2502C>T p.L834= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV52841015; called by muse, mutect2
- UNC93A | c.663C>T p.F221= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs1332785997, COSV100023477, COSV57807066; called by muse, mutect2, varscan2
- UTRN | c.2262C>T p.I754= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV100840115; called by muse, varscan2
- VPS13B | c.2787C>T p.I929= | Silent (SNP) | VAF 29/161 reads (18%) | catalogued as COSV100662806, COSV62144985; called by muse, mutect2, varscan2
- WDR20 | c.900C>T p.G300= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100085282; called by muse, mutect2, varscan2
- WSCD2 | c.1569C>T p.L523= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV99774904; called by muse, mutect2, varscan2
- Z83844.2 | c.618C>T p.F206= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as rs1016592634, COSV60928366; called by muse, mutect2, varscan2
- ZBTB39 | c.2130G>A p.P710= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs140799751; called by muse, mutect2, varscan2
- ZDBF2 | c.3486G>A p.L1162= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV65626825; called by muse, mutect2, varscan2
- ZFP41 | c.39C>T p.T13= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1327494390, COSV100414736; called by muse, mutect2, varscan2
- ZMYND12 | c.513C>T p.H171= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as rs751761298, COSV65342143; called by muse, mutect2, varscan2
- ZMYND15 | c.1890G>A p.R630= (on ENST00000433935 / NM_001136046.3; = p.R591= on NM_032265.2) | Silent (SNP) | VAF 22/159 reads (14%) | catalogued as rs773489203, COSV52642409; called by muse, mutect2, varscan2
- ZNF385A | c.297C>T p.A99= (on ENST00000338010 / NM_001130967.3; = p.A79= on NM_015481.3) | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100566948; called by muse, mutect2, varscan2
- ZNF451 | c.1131C>T p.T377= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV62597996; called by muse, mutect2, varscan2
- ZNF883 | c.960C>T p.P320= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV101432503, COSV71309121; called by muse, mutect2, varscan2
- ZPLD1 | c.954G>A p.R318= (on ENST00000466937 / NM_001329788.1; = p.R334= on NM_175056.2) | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV60354105; called by muse, mutect2, varscan2
- ZRANB3 | c.2535C>T p.D845= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as COSV51504270; called by muse, mutect2, varscan2
- AC017104.4 | chr2:231509131 C>A | 5'Flank (SNP) | VAF 37/182 reads (20%) | called by muse, mutect2, varscan2
- AC024940.1 | n.2863C>T | RNA (SNP) | VAF 78/339 reads (23%) | called by muse, varscan2
- AL136982.4 | n.1015C>T | RNA (SNP) | VAF 26/263 reads (10%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846450 A>G | 5'Flank (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
- ERBB4 | c.82+112131C>T | Intron (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99628343; called by muse, mutect2, varscan2
- KCNK10 | c.37+3666C>T | Intron (SNP) | VAF 12/97 reads (12%) | catalogued as COSV59969645; called by muse, mutect2, varscan2
- MIR1275 | n.71G>A | RNA (SNP) | VAF 13/61 reads (21%) | catalogued as rs754069425; called by muse, mutect2, varscan2
- MIR154 | n.23C>T | RNA (SNP) | VAF 38/155 reads (25%) | called by muse, mutect2, varscan2
- NRG1 | c.502+31185G>A | Intron (SNP) | VAF 15/86 reads (17%) | catalogued as COSV99828117; called by muse, mutect2, varscan2
- OR2W5 | n.1060C>T | RNA (SNP) | VAF 20/81 reads (25%) | catalogued as rs867029459; called by muse, mutect2, varscan2
- PRND | chr20:4732601 G>A | 3'Flank (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- PRR12 | chr19:49595168 C>T | 5'Flank (SNP) | VAF 3/27 reads (11%) | catalogued as COSV55870439; called by muse, mutect2
- RMDN2 | c.453-22067C>A | Intron (SNP) | VAF 13/64 reads (20%) | catalogued as COSV52225941; called by muse, mutect2, varscan2
- RNU6-104P | chr8:43302055 C>T | 5'Flank (SNP) | VAF 19/106 reads (18%) | catalogued as rs1563420049; called by muse, mutect2, varscan2
- SLC8A3 | c.1785-2930C>T | Intron (SNP) | VAF 22/95 reads (23%) | catalogued as COSV53688975, COSV53691622; called by muse, mutect2, varscan2
- SSX6P | n.199T>G | RNA (SNP) | VAF 16/85 reads (19%) | catalogued as rs1556914942; called by muse, mutect2, varscan2
- SSX6P | n.200C>T | RNA (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.10360+5339C>T | Intron (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100621100; called by muse, mutect2, varscan2
